Somatic mutation profile of tumor specimen TCGA-A6-6653-01A (aliquot TCGA-A6-6653-01A-11D-1771-10) from TCGA case TCGA-A6-6653, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 82.1 years (29,996 days).
Specimen TCGA-A6-6653-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbc713fe-c1a3-4557-8a02-94f2153e5184.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6653-10A (Blood Derived Normal), aliquot TCGA-A6-6653-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f9dae36-a988-4fdb-ad25-f03b4e213b74

The open-access MAF lists 1,320 somatic variants for this specimen: 1,002 protein-altering or splice-affecting, 290 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 709, Silent 290, Frame Shift Del 182, Frame Shift Ins 46, Nonsense Mutation 31, Splice Site 17, Intron 13, Splice Region 8, In Frame Del 8, RNA 7, 5'Flank 3, 3'UTR 3.

Variants (750 of 1,320; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.3911dup p.N1304Kfs*7 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ASPM | c.5149dup p.I1717Nfs*24 | Frame Shift Ins (INS) | VAF 38/101 reads (38%) | catalogued as rs199422167; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN1B | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 23/30 reads (77%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1280938448, COSV57430517, COSV57431375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAA | c.2242del p.E748Rfs*16 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs777275355, CM082763, CM128388, CM970554; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MMUT | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs121918251, CM910267, COSV51274211; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 22/44 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1009A>G p.K337E | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV52706901; called by muse, mutect2, varscan2
- ABCA2 | c.3983G>A p.R1328H (on ENST00000614293; = p.R1298H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs370357831; called by muse, mutect2
- ABCA2 | c.2951G>A p.R984H (on ENST00000614293; = p.R954H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs762702619, COSV55801964; called by muse, mutect2, varscan2
- ABCC8 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as CM129772, COSV100217763; called by muse, mutect2, varscan2
- ABI3 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV56800242; called by muse, mutect2, varscan2
- AC008397.2 | c.1622T>C p.L541P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99442323; called by muse, mutect2, varscan2
- ACE | c.2899G>A p.G967S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as rs937878555, COSV52005700; called by muse, mutect2, varscan2
- ACKR1 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.023); catalogued as COSV63672961; called by muse, mutect2, varscan2
- ACLY | c.3296T>C p.M1099T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); catalogued as COSV59862092; called by muse, mutect2, varscan2
- ACP1 | c.167del p.P56Lfs*9 | Frame Shift Del (DEL) | VAF 37/104 reads (36%) | catalogued as rs1325618349; called by mutect2, pindel, varscan2
- ACP2 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57042688; called by muse, mutect2, varscan2
- ACSM3 | c.1301C>A p.P434Q | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55501611; called by muse, mutect2, varscan2
- ACSM4 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.331); catalogued as rs766831767, COSV68067677, COSV68068872; called by muse, mutect2, varscan2
- ACTBL2 | c.49A>G p.M17V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as COSV70661306; called by muse, mutect2, varscan2
- ACTN3 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs775456822, COSV72207602; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADAM10 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as rs1375000211, COSV53051682; called by muse, mutect2, varscan2
- ADAM7 | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV51540477; called by muse, mutect2, varscan2
- ADAMTS20 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67132093; called by muse, mutect2, varscan2
- ADAR | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV52715864; called by muse, mutect2, varscan2
- ADCY5 | c.3133C>T p.P1045S | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59194147; called by muse, mutect2, varscan2
- ADCY6 | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.656); catalogued as rs1421742871, COSV57168141; called by muse, mutect2, varscan2
- ADCY8 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs747303557, COSV53909448; called by muse, mutect2, varscan2
- ADCY9 | c.1958G>A p.G653D | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV53575678; called by muse, mutect2, varscan2
- ADGRL3 | c.2625C>G p.I875M (on ENST00000506720 / NM_001322402.2; = p.I807M on NM_015236.6) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV72230668; called by muse, mutect2, varscan2
- ADPRHL1 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60261410; called by muse, mutect2, varscan2
- AFDN | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV60045527; called by muse, mutect2, varscan2
- AFDN | c.4741G>A p.E1581K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs776910572, COSV60045537; called by muse, mutect2, varscan2
- AFF2 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1334238002, COSV53976319; called by muse, mutect2, varscan2
- AGAP1 | c.1757A>G p.Q586R (on ENST00000304032 / NM_001037131.3; = p.Q533R on NM_014914.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs778746496, COSV100367175; called by muse, mutect2
- AGAP6 | c.805C>T p.R269* (on ENST00000374056 / NM_001365867.1; = p.R292* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | catalogued as rs782351142, COSV100929165; called by muse, mutect2, varscan2
- AGBL5 | c.1266del p.E424Rfs*44 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs747733044, COSV59935415; called by mutect2, pindel, varscan2
- AKAP12 | c.2878G>A p.A960T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV99484485; called by muse, varscan2
- AKR1D1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54337699; called by muse, mutect2, varscan2
- AL121899.2 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs150052126; called by muse, mutect2, varscan2
- ALPK3 | c.1553C>A p.P518H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV99362067; called by muse, mutect2, varscan2
- ALPP | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377839356, COSV101235199; called by mutect2, varscan2
- ALX4 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763248407, COSV61326642; called by muse, mutect2, varscan2
- AMER2 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV63437738; called by muse, mutect2, varscan2
- AMIGO1 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs371766167; called by muse, mutect2, varscan2
- AMPD2 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs774595273, COSV56648047; called by muse, mutect2, varscan2
- ANKMY1 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV56034689; called by muse, mutect2, varscan2
- ANKRD17 | c.7300C>T p.R2434C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); catalogued as rs143161842; called by muse, mutect2, varscan2
- ANKRD17 | c.2202A>T p.L734F | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100430029; called by muse, mutect2
- ANKRD52 | c.2101G>A p.V701M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); catalogued as rs1295164791, COSV57284579; called by muse, mutect2, varscan2
- ANKRD52 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371235467; called by muse, mutect2, varscan2
- ANXA3 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); catalogued as COSV53714161, COSV53714867; called by muse, mutect2, varscan2
- AOPEP | c.2386C>T p.R796C (on ENST00000375315 / NM_001193329.1; = p.R697C on NM_032823.5) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs375571307, COSV52990723; called by muse, mutect2, varscan2
- AP2A2 | c.1100C>T p.T367M | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs774701302, COSV100173367; called by muse, mutect2, varscan2
- AP5B1 | c.1445T>C p.V482A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100376167; called by muse, mutect2
- AP5Z1 | c.2086del p.Q696Rfs*6 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs771683676, COSV100804281; called by mutect2, pindel, varscan2
- APBA1 | c.2458A>G p.M820V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV55228612; called by muse, mutect2, varscan2
- APOBEC2 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1415911773, COSV55107808; called by muse, mutect2, varscan2
- APOL2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs377641018; called by muse, mutect2, varscan2
- ARAP1 | c.2674C>T p.R892C (on ENST00000393609 / NM_001040118.2; = p.R647C on NM_015242.4) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs372507219; called by muse, mutect2, varscan2
- ARAP1 | c.1005del p.D335Efs*16 (on ENST00000393609 / NM_001040118.2; = p.D90Efs*16 on NM_015242.4) | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as COSV61991347; called by mutect2, pindel, varscan2
- ARHGAP20 | c.935G>T p.S312I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV52811928; called by muse, mutect2, varscan2
- ARHGAP28 | c.1065del p.F355Lfs*8 (on ENST00000383472 / NM_001366230.1; = p.F196Lfs*8 on NM_001010000.3) | Frame Shift Del (DEL) | VAF 52/94 reads (55%) | catalogued as rs1567977926, COSV51634082; called by mutect2, varscan2
- ARHGEF3 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs768543223, COSV56323655, COSV56327209; called by muse, mutect2, varscan2
- ARL13A | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773610188, COSV65880170; called by muse, mutect2, varscan2
- ARPC2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1041531687, COSV55284943; called by muse, mutect2, varscan2
- ASH1L | c.8515C>T p.R2839* (on ENST00000368346 / NM_001366177.2; = p.R2834* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 53/125 reads (42%) | catalogued as COSV64206891; called by muse, mutect2, varscan2
- ASH1L | c.2134del p.R712Efs*23 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs1558150870; called by mutect2, varscan2
- ATG2A | c.4409C>T p.T1470M | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs372670898; called by muse, mutect2, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 22/39 reads (56%) | catalogued as rs772363145; called by mutect2, varscan2
- ATXN7L2 | c.1236G>A p.A412= | Splice Region (SNP) | VAF 10/29 reads (34%) | catalogued as COSV60204974; called by muse, mutect2, varscan2
- B4GAT1 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV60820153; called by muse, mutect2, varscan2
- BCAS3 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs754556946, COSV66769728; called by muse, mutect2, varscan2
- BCL11A | c.1927G>A p.G643R (on ENST00000335712 / NM_001365609.1; = p.G677R on NM_018014.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1393873085, COSV59630622; called by muse, mutect2, varscan2
- BEST4 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs773733162, COSV64733978; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | catalogued as rs755506199; called by mutect2, varscan2
- BLMH | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55585621; called by muse, mutect2, varscan2
- BMP1 | c.584del p.G195Afs*56 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as COSV60475848, COSV60484551; called by mutect2, pindel, varscan2
- BNIP5 | c.1702dup p.Y568Lfs*24 | Frame Shift Ins (INS) | VAF 11/31 reads (35%) | catalogued as rs747868798; called by mutect2, varscan2
- BPI | c.1196T>C p.V399A (on ENST00000262865; = p.V395A on NM_001725.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as COSV99480989; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as COSV56263190; called by mutect2, pindel, varscan2
- BRD1 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53457717; called by muse, mutect2, varscan2
- BRD8 | c.3120+2T>C p.X1040_splice | Splice Site (SNP) | VAF 11/74 reads (15%) | catalogued as COSV54727055; called by muse, mutect2, varscan2
- BRD8 | c.842C>A p.P281H (on ENST00000254900 / NM_139199.2; = p.P354H on NM_006696.4) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99137707; called by muse, mutect2, varscan2
- BRINP1 | c.194T>A p.F65Y | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99777025; called by muse, mutect2, varscan2
- BSN | c.10828C>T p.R3610* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as rs1399229458, COSV56518920; called by muse, mutect2, varscan2
- C10orf90 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as COSV52955918; called by muse, mutect2, varscan2
- C1orf100 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as rs200838303; called by muse, mutect2, varscan2
- C1orf112 | c.66+1G>A p.X22_splice | Splice Site (SNP) | VAF 102/244 reads (42%) | catalogued as COSV53678001; called by muse, mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C6 | c.484A>C p.N162H | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV54710803; called by muse, mutect2, varscan2
- C7orf31 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99384188; called by muse, mutect2, varscan2
- CAB39L | c.285del p.D96Mfs*2 | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | catalogued as COSV61714509; called by pindel, varscan2
- CACNA1S | c.5207C>A p.A1736E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as COSV62939859; called by muse, mutect2, varscan2
- CALML3 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.594); catalogued as COSV100178910; called by muse, varscan2
- CAMK1D | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs754487170, COSV66611822; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 39/105 reads (37%) | catalogued as rs1375954479; called by mutect2, varscan2
- CAMTA1 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV57911865; called by muse, mutect2, varscan2
- CANT1 | c.210del p.T71Pfs*59 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | catalogued as COSV100185352; called by mutect2, pindel, varscan2
- CARMIL2 | c.2762C>A p.P921H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV58026782; called by muse, varscan2
- CARS2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV57286295; called by muse, varscan2
- CAVIN2 | c.628dup p.H210Pfs*3 | Frame Shift Ins (INS) | VAF 36/103 reads (35%) | catalogued as rs745935100; called by mutect2, pindel, varscan2
- CBLN4 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV50353020; called by muse, mutect2, varscan2
- CCDC17 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs371774040, COSV59647225; called by muse, mutect2, varscan2
- CCDC178 | c.2521C>T p.Q841* (on ENST00000383096 / NM_001105528.3; = p.Q803* on NM_198995.3) | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV55764443; called by muse, mutect2, varscan2
- CCDC88A | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV55062251; called by muse, mutect2, varscan2
- CCDC88A | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as COSV55062269; called by muse, mutect2, varscan2
- CCDC88C | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376282183; called by muse, mutect2, varscan2
- CCDC92 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs776087763, COSV99435631, COSV99435929; called by muse, mutect2, varscan2
- CCDC9B | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs572485964, COSV66875213, COSV66875496; called by muse, mutect2, varscan2
- CCNJL | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs773517273, COSV57443366; called by muse, mutect2, varscan2
- CCR1 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs199658624, COSV56121799; called by muse, mutect2, varscan2
- CD14 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57370786; called by muse, mutect2, varscan2
- CD163L1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs757615416, COSV58015867; called by muse, mutect2, varscan2
- CD180 | c.1731C>A p.N577K | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs374556833, COSV56517743; called by muse, mutect2, varscan2
- CD9 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50530480; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDH10 | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as rs1382510928, COSV52593768; called by muse, mutect2, varscan2
- CDH13 | c.342del p.D116Tfs*31 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs1567763530, COSV51808407; called by mutect2, pindel
- CDH19 | c.1510C>G p.H504D | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV50959936; called by muse, varscan2
- CDH6 | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs955262652, COSV54070646; called by muse, mutect2, varscan2
- CDH8 | c.292T>C p.Y98H | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54869263; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2633C>T p.T878M | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs112982005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDR2L | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1192999281, COSV61501258; called by muse, mutect2, varscan2
- CEACAM20 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.073); catalogued as COSV57601838; called by muse, mutect2, varscan2
- CHD6 | c.7987del p.D2663Tfs*59 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as COSV64690019; called by mutect2, pindel, varscan2
- CHD6 | c.4600C>T p.R1534C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs774503575, COSV64690944; called by muse, mutect2, varscan2
- CHD8 | c.7148C>T p.P2383L (on ENST00000646647 / NM_001170629.2; = p.P2104L on NM_020920.4) | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs751755659, COSV63036876; called by muse, mutect2, varscan2
- CHD8 | c.3307G>T p.G1103C (on ENST00000646647 / NM_001170629.2; = p.G824C on NM_020920.4) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67870672; called by muse, mutect2, varscan2
- CHP2 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773423633, COSV55649193; called by muse, mutect2, varscan2
- CHRM4 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.241); catalogued as COSV100642140; called by muse, mutect2, varscan2
- CHRM5 | c.1060dup p.S354Kfs*2 | Frame Shift Ins (INS) | VAF 11/41 reads (27%) | catalogued as rs1233205595; called by mutect2, pindel, varscan2
- CHST2 | c.723dup p.R242Afs*92 | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | catalogued as rs766570662; called by mutect2, pindel, varscan2
- CIT | c.4235G>A p.G1412D | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55870002; called by muse, mutect2, varscan2
- CIZ1 | c.1133A>G p.Q378R | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.448); catalogued as rs1446914864, COSV52971649; called by muse, mutect2, varscan2
- CKAP5 | c.3932C>T p.A1311V | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as rs766170007, COSV56368132; called by muse, mutect2, varscan2
- CLASP1 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs150410557; called by muse, mutect2, varscan2
- CLCN2 | c.2594G>A p.S865N | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV55601356; called by muse, mutect2, varscan2
- CLCN6 | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as rs769924243, COSV100412290, COSV56740330; called by muse, mutect2, varscan2
- CLEC4F | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV55479553; called by muse, mutect2, varscan2
- CLMN | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.456); catalogued as rs182308272, COSV54182567; called by muse, mutect2, varscan2
- CLPTM1 | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.457); catalogued as rs770360744, COSV61611161; called by mutect2, varscan2
- CLRN2 | c.352T>C p.F118L | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV72512556; called by muse, mutect2, varscan2
- CNGA1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs756125453, COSV62054431; called by muse, mutect2, varscan2
- CNPPD1 | c.1128dup p.W377Lfs*50 | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | catalogued as rs764842458; called by mutect2, pindel, varscan2
- CNTN6 | c.1153C>A p.Q385K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63173456; called by muse, mutect2, varscan2
- CNTNAP4 | c.1465G>A p.G489S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV56682114; called by muse, mutect2, varscan2
- COL22A1 | c.3014C>T p.A1005V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.062); catalogued as COSV57338357; called by muse, mutect2, varscan2
- COL27A1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1003403359, COSV61926482; called by muse, mutect2, varscan2
- COL4A3 | c.4571C>T p.S1524L | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121912825, CM940308, COSV101170547; called by muse, mutect2, varscan2
- COL4A5 | c.4534C>T p.R1512C | Missense Mutation (SNP) | VAF 123/151 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs979462661, COSV60362305; called by muse, mutect2, varscan2
- COL6A6 | c.2566G>T p.D856Y | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV62021471, COSV62026103; called by muse, mutect2, varscan2
- COL9A2 | c.1216-1G>T p.X406_splice | Splice Site (SNP) | VAF 23/66 reads (35%) | catalogued as COSV65622919; called by muse, mutect2, varscan2
- COLGALT2 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs779082349, COSV100730886; called by muse, mutect2, varscan2
- COQ7 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs201474239, COSV58981417; called by muse, mutect2, varscan2
- COQ8B | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV54575034; called by muse, mutect2, varscan2
- CP | c.1864T>C p.S622P | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52830882; called by muse, mutect2
- CPAMD8 | c.3153del p.H1052Ifs*127 (on ENST00000651564; = p.H1005Ifs*127 on NM_015692.5) | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | catalogued as rs750161916, COSV71597321; called by mutect2, pindel, varscan2
- CPEB3 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1211150494, COSV56456831; called by muse, mutect2, varscan2
- CPNE7 | c.1462G>A p.V488M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs369027383; called by mutect2, varscan2
- CPSF6 | c.961G>T p.G321C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV57014801; called by muse, mutect2, varscan2
- CPT1C | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770712989, COSV54919487; called by muse, mutect2, varscan2
- CPZ | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.005); catalogued as rs760632747; called by muse, varscan2
- CRB1 | c.2137G>A p.A713T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.322); catalogued as COSV66330703; called by muse, mutect2, varscan2
- CREM | c.910C>T p.R304* (on ENST00000429130; = p.R259* on NM_181571.3) | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as rs770911193, COSV59767320; called by muse, mutect2, varscan2
- CRTAC1 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as rs576681356, COSV53997998; called by muse, mutect2, varscan2
- CRTC1 | c.1277dup p.E427Rfs*24 | Frame Shift Ins (INS) | VAF 28/72 reads (39%) | catalogued as rs760791352; called by mutect2, varscan2
- CRYBG1 | c.5152C>T p.R1718* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as rs141818175; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CSF2RA | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.626); catalogued as COSV62624766; called by muse, mutect2, varscan2
- CSMD1 | c.3281G>T p.W1094L (on ENST00000520002; = p.W1093L on NM_033225.6) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59329039; called by muse, mutect2, varscan2
- CSMD2 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs748711933, COSV53904504, COSV53915786; called by muse, mutect2, varscan2
- CSMD3 | c.4723T>C p.Y1575H (on ENST00000297405 / NM_001363185.1; = p.Y1471H on NM_052900.3) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV52190117; called by muse, mutect2, varscan2
- CSPP1 | c.2422C>T p.R808W (on ENST00000676605; = p.R767W on NM_024790.6) | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369228037; called by muse, mutect2, varscan2
- CTC1 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs780151711, COSV100236832; called by muse, mutect2, varscan2
- CTC1 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV59853458; called by muse, mutect2, varscan2
- CTH | c.724+2T>C p.X242_splice | Splice Site (SNP) | VAF 35/87 reads (40%) | catalogued as COSV61008602; called by muse, mutect2, varscan2
- CTNNA3 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57719424; called by muse, mutect2, varscan2
- CTSC | c.959C>A p.A320D | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV57058032; called by muse, mutect2, varscan2
- CUL4A | c.820G>A p.V274I (on ENST00000375440 / NM_001008895.4; = p.V174I on NM_003589.3) | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs201623121, COSV58372743; called by muse, mutect2, varscan2
- CWF19L2 | c.977del p.N326Ifs*19 | Frame Shift Del (DEL) | VAF 75/203 reads (37%) | catalogued as COSV56519025; called by mutect2, pindel, varscan2
- CYLC2 | c.880_882del p.K294del | In Frame Del (DEL) | VAF 14/127 reads (11%) | catalogued as rs924758805; called by pindel, varscan2
- CYP26A1 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56418440; called by muse, mutect2, varscan2
- DBT | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as CD126897, COSV64495525; called by muse, mutect2, varscan2
- DCAF1 | c.3895G>A p.V1299M | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV60043117; called by muse, mutect2, varscan2
- DCAF1 | c.1372T>C p.C458R | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60043123; called by muse, mutect2, varscan2
- DCAF16 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.046); catalogued as COSV66384221; called by muse, mutect2, varscan2
- DCC | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs776292641, COSV59104390; called by muse, mutect2, varscan2
- DCC | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59104404; called by muse, mutect2, varscan2
- DDIAS | c.1038G>T p.E346D | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100231469; called by muse, mutect2, varscan2
- DDX18 | c.1012A>C p.I338L | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV54306790; called by muse, mutect2, varscan2
- DDX25 | c.1308del p.R437Afs*11 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as COSV104375331; called by mutect2, pindel
- DDX3Y | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267607; called by muse, mutect2, varscan2
- DDX43 | c.437-2A>C p.X146_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100946512; called by mutect2, varscan2
- DDX47 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs766816468, COSV61911461; called by muse, mutect2, varscan2
- DEF6 | c.1835A>C p.E612A | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV100359547; called by muse, mutect2, varscan2
- DENND1C | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs751299679, COSV67373381; called by muse, mutect2, varscan2
- DENND1C | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67373389; called by muse, mutect2, varscan2
- DGCR8 | c.1342T>C p.F448L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV61226847; called by muse, mutect2, varscan2
- DGKB | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1413885392, COSV51785383; called by muse, mutect2, varscan2
- DHX16 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs993567817, COSV100905258; called by muse, mutect2, varscan2
- DHX30 | c.3110G>A p.R1037Q (on ENST00000445061 / NM_138615.3; = p.R998Q on NM_014966.3) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs1270102369, COSV53137902; called by muse, mutect2, varscan2
- DHX8 | c.1408G>A p.G470S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs758860287, COSV52253607; called by muse, mutect2, varscan2
- DIDO1 | c.2133del p.F711Lfs*22 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | catalogued as COSV56621054; called by mutect2, pindel, varscan2
- DIDO1 | c.1425del p.E476Rfs*4 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs762377755; called by mutect2, varscan2
- DIO3 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV63773498; called by muse, mutect2, varscan2
- DLAT | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs781951438, COSV54769256; called by muse, mutect2, varscan2
- DMC1 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as COSV53259289; called by muse, varscan2
- DNAH3 | c.2006C>T p.T669M | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs755971290, COSV54524283; called by muse, mutect2, varscan2
- DNAH5 | c.11464C>T p.R3822W | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746375013, COSV54213996, COSV54232265; called by muse, mutect2, varscan2
- DNAH7 | c.9908G>T p.R3303I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.092); catalogued as COSV56766542; called by muse, mutect2, varscan2
- DNAH9 | c.7949del p.P2650Hfs*2 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | catalogued as COSV52362670; called by mutect2, varscan2
- DNAJB5 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.414); catalogued as rs766646645, COSV56625690; called by muse, mutect2, varscan2
- DNAJC3 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs144153992; called by muse, varscan2
- DNAJC4 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54173660; called by muse, mutect2
- DNM3 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 46/109 reads (42%) | catalogued as COSV62458485; called by muse, mutect2, varscan2
- DOCK9 | c.5884C>T p.R1962W (on ENST00000376460 / NM_001366676.2; = p.R1963W on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs377181227, COSV100241169; called by muse, mutect2, varscan2
- DOCK9 | c.3532C>T p.R1178W (on ENST00000376460 / NM_001366676.2; = p.R1179W on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1185344656, COSV59630497; called by muse, mutect2, varscan2
- DOCK9 | c.3357G>T p.R1119S (on ENST00000376460 / NM_001366676.2; = p.R1120S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV59630505; called by muse, mutect2, varscan2
- DPP3 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs755183144, COSV100855748; called by muse, mutect2, varscan2
- DPY19L2 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as COSV60543351, COSV60543626; called by muse, mutect2, varscan2
- DPYS | c.452A>G p.Q151R | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100680174, COSV60908099; called by muse, mutect2, varscan2
- DRD1 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV67104677; called by muse, mutect2, varscan2
- DRD5 | c.1253T>C p.V418A | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV58578323; called by muse, mutect2, varscan2
- DSCAML1 | c.2500G>T p.G834C (on ENST00000321322; = p.G774C on NM_020693.4) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58391293; called by muse, mutect2, varscan2
- DYRK2 | c.563C>T p.A188V (on ENST00000344096 / NM_006482.3; = p.A115V on NM_003583.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV59846220; called by muse, mutect2, varscan2
- DZANK1 | c.721C>T p.R241C (on ENST00000262547 / NM_001099407.1; = p.R42C on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs749696361, COSV52751541; called by muse, mutect2, varscan2
- DZIP1L | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV59521158; called by muse, mutect2, varscan2
- E2F4 | c.836A>G p.K279R | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.971); catalogued as COSV100681975; called by muse, varscan2
- ECM2 | c.1604+2T>C p.X535_splice | Splice Site (SNP) | VAF 14/121 reads (12%) | catalogued as COSV60740760; called by muse, mutect2, varscan2
- EEF1A2 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV53205168; called by muse, mutect2, varscan2
- EEF1D | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs200146410; called by muse, mutect2, varscan2
- EGLN2 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs1472809305, COSV58280071; called by muse, mutect2, varscan2
- EGR4 | c.414G>T p.R138S (on ENST00000545030; = p.R35S on NM_001965.4) | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV71532055; called by muse, mutect2, varscan2
- EHBP1L1 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757028790, COSV58573300; called by muse, mutect2, varscan2
- EHMT2 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.602); catalogued as COSV64993867; called by muse, mutect2, varscan2
- ELMO3 | c.2216G>A p.R739H (on ENST00000652269; = p.R686H on NM_024712.5) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs200461796, COSV58527269; called by muse, mutect2, varscan2
- ELN | c.163+2T>A p.X55_splice | Splice Site (SNP) | VAF 11/21 reads (52%) | catalogued as CS101100, COSV52706956, COSV99333224; called by muse, mutect2, varscan2
- ELOVL1 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs754465886, COSV100196504, COSV60522186; called by muse, mutect2, varscan2
- ELOVL3 | c.80G>T p.R27M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100892847, COSV64174945; called by muse, mutect2, varscan2
- ENTPD2 | c.1298C>T p.A433V (on ENST00000355097 / NM_203468.3; = p.A410V on NM_001246.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV57075482, COSV57076792; called by muse, mutect2, varscan2
- EPB41L1 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs111421912, COSV52438227; called by muse, mutect2, varscan2
- EPB41L3 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV59454671; called by muse, mutect2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 50/124 reads (40%) | catalogued as rs35675992; called by mutect2, varscan2
- EPS8L1 | c.952G>A p.D318N (on ENST00000201647 / NM_133180.3; = p.D191N on NM_017729.3) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV52382465; called by muse, mutect2, varscan2
- ERICH5 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV100582885; called by muse, varscan2
- ESR2 | c.106T>C p.Y36H | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50831849; called by muse, mutect2, varscan2
- EVPL | c.5260C>T p.R1754C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); catalogued as rs763141538, COSV56911545; called by muse, mutect2, varscan2
- EXOC3L2 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs139655836; called by muse, mutect2, varscan2
- EXOC7 | c.810G>A p.G270= | Splice Region (SNP) | VAF 11/44 reads (25%) | catalogued as rs1278246300, COSV58741855; called by muse, mutect2, varscan2
- FAAP24 | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.664); catalogued as COSV54288338; called by muse, mutect2, varscan2
- FADS1 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as COSV99952578; called by muse, varscan2
- FAM126B | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV53772763; called by muse, mutect2, varscan2
- FAM13A | c.2008C>T p.R670* | Nonsense Mutation (SNP) | VAF 40/107 reads (37%) | catalogued as rs377672753; called by muse, mutect2, varscan2
- FAM171A1 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.346); catalogued as rs762494380, COSV65313536, COSV65320245; called by muse, mutect2, varscan2
- FAM174B | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59264212; called by muse, mutect2, varscan2
- FAM183A | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.311); catalogued as COSV58922114; called by muse, mutect2, varscan2
- FAM32A | c.74+1G>A p.X25_splice | Splice Site (SNP) | VAF 16/43 reads (37%) | catalogued as COSV54624514; called by muse, mutect2, varscan2
- FAM32A | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54624523; called by muse, mutect2, varscan2
- FAN1 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100756057, COSV62950739; called by muse, mutect2, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 30/74 reads (41%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FASN | c.6595G>A p.E2199K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs747906170, COSV60755340; called by muse, mutect2, varscan2
- FAT3 | c.3588del p.F1196Lfs*9 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | catalogued as COSV53094622; called by mutect2, varscan2
- FAT4 | c.10156G>T p.A3386S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.995); catalogued as COSV58687320; called by muse, mutect2, varscan2
- FBN3 | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs769704081, COSV54461888; called by muse, mutect2, varscan2
- FBXW11 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51609396; called by muse, mutect2, varscan2
- FBXW4 | c.1584+2T>C p.X528_splice | Splice Site (SNP) | VAF 18/42 reads (43%) | catalogued as COSV58708025; called by muse, mutect2, varscan2
- FCAMR | c.203A>C p.H68P | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1410053277, COSV61367912; called by muse, mutect2, varscan2
- FCGRT | c.320del p.G107Efs*29 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs1568698688; called by mutect2, pindel, varscan2
- FGD2 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs774689896, COSV51463840, COSV51463919; called by muse, mutect2, varscan2
- FIBCD1 | c.1231T>C p.Y411H | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53393717; called by muse, mutect2, varscan2
- FKBPL | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.015); catalogued as COSV64322497; called by muse, mutect2, varscan2
- FLG | c.6577del p.T2193Hfs*226 | Frame Shift Del (DEL) | VAF 84/262 reads (32%) | catalogued as COSV100912393; called by mutect2, pindel, varscan2
- FLG | c.5032G>A p.G1678R | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.999); catalogued as COSV64242375; called by muse, mutect2, varscan2
- FLNB | c.4787del p.G1596Vfs*33 | Frame Shift Del (DEL) | VAF 25/75 reads (33%) | catalogued as CM165640, COSV99912687; called by mutect2, pindel, varscan2
- FLRT2 | c.1405C>A p.R469S | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.883); catalogued as rs755278961, COSV58142064, COSV58143564; called by muse, mutect2, varscan2
- FMN2 | c.3046G>A p.G1016R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV100147293; called by muse, varscan2
- FMNL3 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs773190923, COSV53301582; called by muse, mutect2, varscan2
- FMOD | c.971G>T p.R324M | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV61610061; called by muse, mutect2, varscan2
- FNTB | c.1047del p.L350Ffs*18 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs768774237; called by mutect2, pindel, varscan2
- FOXI2 | c.640G>T p.G214W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100511119; called by muse, mutect2, varscan2
- FOXN3 | c.1174G>A p.D392N (on ENST00000261302; = p.D370N on NM_005197.4) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as rs754903884, COSV54306832; called by mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FRAT1 | c.673C>A p.L225M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV64017466; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FSCN1 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs756163037, COSV61018379; called by muse, mutect2, varscan2
- FSIP2 | c.16948C>T p.R5650* | Nonsense Mutation (SNP) | VAF 48/103 reads (47%) | catalogued as rs746547008, COSV100555848, COSV58087277; called by muse, mutect2, varscan2
- FXR1 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs1417565250, COSV59763204; called by muse, mutect2, varscan2
- FYN | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | catalogued as COSV57614634; called by muse, mutect2, varscan2
- GABRA5 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59480009; called by muse, mutect2, varscan2
- GABRG1 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV54954591; called by muse, mutect2, varscan2
- GABRG3 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV100409573, COSV61510788; called by muse, mutect2, varscan2
- GADD45GIP1 | c.585_586del p.K196Tfs*43 | Frame Shift Del (DEL) | VAF 48/115 reads (42%) | catalogued as rs752340689; called by mutect2, pindel, varscan2
- GALE | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs553417178, COSV52526061; called by muse, mutect2, varscan2
- GAP43 | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59344544; called by muse, mutect2, varscan2
- GCH1 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV99582126; called by muse, mutect2, varscan2
- GCN1 | c.7295T>C p.L2432P | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.878); catalogued as COSV100326066; called by muse, mutect2, varscan2
- GDF6 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV54625250, COSV54626250; called by muse, mutect2, varscan2
- GGA1 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.234); catalogued as rs765255006, COSV57330104; called by muse, mutect2, varscan2
- GIMAP5 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs202237347; called by muse, mutect2, varscan2
- GLIS3 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs757448015, COSV60929422; called by muse, mutect2, varscan2
- GLTP | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs141894554; called by muse, mutect2, varscan2
- GMPPA | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100354893; called by muse, mutect2, varscan2
- GOSR1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs759139582, COSV99853816; called by muse, varscan2
- GP6 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs1282834493, COSV59977494; called by muse, mutect2, varscan2
- GPATCH3 | c.191_192del p.S64Cfs*10 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs1444759010; called by pindel, varscan2
- GPBP1 | c.1220T>C p.L407S | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53311766; called by muse, mutect2, varscan2
- GPR32 | c.1063del p.R355Gfs*16 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs751525642; called by mutect2, pindel, varscan2
- GPT | c.1419dup p.E475Gfs*72 | Frame Shift Ins (INS) | VAF 27/77 reads (35%) | catalogued as rs776744432; called by mutect2, pindel, varscan2
- GREB1 | c.3886C>T p.R1296C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1417517306, COSV52187899; called by muse, mutect2
- GRIA1 | c.1965G>T p.K655N | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53604507; called by muse, mutect2, varscan2
- GRID2 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs760655946, COSV56184633; called by muse, mutect2, varscan2
- GRIK5 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491414; called by muse, mutect2, varscan2
- GRIN1 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); catalogued as COSV59294604; called by muse, mutect2, varscan2
- GRM2 | c.1652C>T p.T551I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV56585145; called by muse, mutect2, varscan2
- GRM6 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs766682788, COSV99179430; called by mutect2, varscan2
- GRM6 | c.727dup p.V243Gfs*40 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | catalogued as rs281865186; ClinVar: not provided; called by mutect2, varscan2
- GRN | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as rs142926942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GTF2A1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.067); catalogued as COSV53337272; called by muse, mutect2, varscan2
- GTF3C1 | c.4489G>A p.V1497M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); catalogued as rs751187181, COSV62241517; called by muse, mutect2, varscan2
- GTF3C1 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs745531613, COSV62241522; called by muse, mutect2, varscan2
- GTPBP3 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50178873; called by muse, mutect2, varscan2
- GUCY1B1 | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100025958, COSV52379409; called by muse, mutect2, varscan2
- H2BC18 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1405984120, COSV58944326; called by muse, mutect2, varscan2
- H3C4 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as COSV100587281; called by muse, mutect2, varscan2
- HBS1L | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs777731477, COSV59020988; called by muse, mutect2, varscan2
- HCAR2 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.588); catalogued as COSV61024964; called by muse, mutect2, varscan2
- HCAR3 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.588); catalogued as COSV100811810; called by muse, mutect2, varscan2
- HECA | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759180001, COSV62769031; called by muse, mutect2, varscan2
- HELZ2 | c.6283C>T p.P2095S (on ENST00000467148 / NM_001037335.2; = p.P1526S on NM_033405.3) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs767837261, COSV71295989; called by muse, mutect2, varscan2
- HERC1 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 41/51 reads (80%) | catalogued as COSV71246022; called by muse, mutect2, varscan2
- HERC2 | c.4313G>A p.R1438H | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs757170828, COSV55325043; called by muse, mutect2, varscan2
- HERC2 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs780970472, COSV55325058; called by muse, mutect2, varscan2
- HEYL | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1036415171, COSV65721644; called by muse, mutect2, varscan2
- HIP1 | c.1081A>G p.N361D | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV61186222; called by muse, mutect2, varscan2
- HKDC1 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63575895; called by muse, mutect2, varscan2
- HMG20B | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as COSV53571837; called by muse, mutect2, varscan2
- HOXC11 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1375070970, COSV99678557; called by muse, mutect2, varscan2
- HSPA1L | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65149175; called by muse, mutect2, varscan2
- HSPG2 | c.11855G>A p.R3952H | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs769541964, COSV100760952; called by muse, mutect2, varscan2
- HTT | c.6630G>T p.G2210= | Splice Region (SNP) | VAF 20/57 reads (35%) | catalogued as COSV61862663; called by muse, mutect2, varscan2
- HVCN1 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs772902585, COSV54371866; called by muse, mutect2, varscan2
- IGKV4-1 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777621314; called by muse, mutect2, varscan2
- IGSF10 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV56785836, COSV99176611; called by muse, mutect2, varscan2
- IKZF3 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1428090962, COSV53099562; called by muse, mutect2, varscan2
- IKZF5 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV64397577; called by muse, mutect2, varscan2
- IL9R | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV54900040; called by muse, mutect2, varscan2
- INO80C | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as rs768152671, COSV52034254; called by muse, mutect2, varscan2
- INPP4B | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as rs1330358087, COSV99526997; called by muse, mutect2, varscan2
- IPO7 | c.869A>G p.E290G | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV65685230; called by muse, mutect2, varscan2
- IRF7 | c.446C>T p.T149M (on ENST00000397566; = p.T136M on NM_001572.5) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs545358325, COSV99213568; called by muse, mutect2, varscan2
- IRGQ | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60670747; called by muse, mutect2, varscan2
- ISLR2 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs768143063, COSV62302232; called by muse, mutect2, varscan2
- ITGA10 | c.1265del p.P422Lfs*50 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs782013321; called by mutect2, pindel, varscan2
- ITGB2 | c.1310T>C p.V437A (on ENST00000302347; = p.V413A on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100186152; called by muse, mutect2, varscan2
- JAZF1 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52238196, COSV52248341; called by muse, mutect2, varscan2
- JMJD6 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57970785; called by muse, mutect2, varscan2
- KAT14 | c.1892C>T p.T631M | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs781727666, COSV66609342; called by muse, varscan2
- KBTBD7 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as rs538150416, COSV65266994; called by muse, mutect2, varscan2
- KCNB1 | c.1469G>T p.W490L | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.446); catalogued as COSV65568436, COSV65570497; called by muse, mutect2, varscan2
- KCNB2 | c.2489G>A p.S830N | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV73050419; called by muse, mutect2, varscan2
- KCNH5 | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV100528265; called by muse, mutect2
- KCNJ16 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99388770; called by mutect2, varscan2
- KCNJ4 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as rs761299177, COSV57856726, COSV57858583; called by muse, mutect2, varscan2
- KCNK1 | c.289T>C p.S97P | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100786039; called by muse, mutect2, varscan2
- KCNMA1 | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV54250433; called by muse, varscan2
- KCTD3 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV52067000, COSV99379859; called by muse, mutect2, varscan2
- KDM5A | c.3601T>C p.S1201P | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV66992614; called by mutect2, varscan2
- KDM6B | c.4301C>T p.T1434M | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.33); catalogued as rs1401991604, COSV54681890; called by muse, mutect2, varscan2
- KIAA1549 | c.4298C>T p.T1433M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs141076075; called by muse, varscan2
- KIF13A | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276991766, COSV99438299; called by muse, varscan2
- KIF16B | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373271206, COSV61706607; called by muse, mutect2, varscan2
- KIF20A | c.2120C>T p.T707I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as COSV67509874; called by muse, mutect2, varscan2
- KIF21A | c.3620G>A p.R1207K (on ENST00000361418 / NM_001378440.1; = p.R1194K on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100735691; called by muse, mutect2, varscan2
- KIF21B | c.1212G>A p.A404= | Splice Region (SNP) | VAF 24/89 reads (27%) | catalogued as rs371524692; called by muse, mutect2, varscan2
- KIF26B | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772241455, COSV63642188; called by muse, mutect2, varscan2
- KLC2 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV57582768; called by muse, mutect2, varscan2
- KLHDC7A | c.2305A>G p.T769A | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV101272855; called by muse, mutect2, varscan2
- KLHL28 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as rs1295442130, COSV61888220; called by muse, mutect2
- KLHL4 | c.2096A>C p.E699A | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.2); PolyPhen benign (0.217); catalogued as COSV64142823; called by muse, mutect2, varscan2
- KMT2B | c.5255G>A p.R1752Q | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs759709546, COSV55861722; called by muse, mutect2, varscan2
- KMT2D | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs952760497, COSV56423724, COSV56443354; called by muse, mutect2, varscan2
- KRAS | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55738907; called by muse, mutect2, varscan2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 28/71 reads (39%) | catalogued as rs761148574; called by mutect2, varscan2
- KRT23 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138435929; called by muse, mutect2, varscan2
- KRT32 | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV56786743; called by muse, mutect2, varscan2
- KRT38 | c.1309T>G p.C437G | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV55846142; called by muse, mutect2, varscan2
- KRTAP5-2 | c.278G>C p.G93A | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.157); catalogued as COSV101295131; called by muse, varscan2
- KRTAP5-2 | c.248G>C p.G83A | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.208); catalogued as COSV69014976; called by muse, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | catalogued as rs770565486; called by mutect2, varscan2
- KY | c.1523A>C p.Q508P | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.088); catalogued as COSV71017409, COSV71017508; called by muse, mutect2, varscan2
- LAMA2 | c.5468G>A p.S1823N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as rs777082683, COSV70347932; called by muse, mutect2, varscan2
- LAMA5 | c.9934G>A p.A3312T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs774270130, COSV99442506; called by muse, mutect2, varscan2
- LAMA5 | c.5923G>A p.G1975S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs781064138, COSV53360759; called by muse, mutect2, varscan2
- LAMA5 | c.3517G>A p.V1173M | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs780809601, COSV53367618; called by muse, mutect2, varscan2
- LAMB2 | c.3059C>T p.A1020V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.378); catalogued as COSV59733824; called by muse, mutect2, varscan2
- LCN12 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556249758, COSV65422175; called by muse, mutect2, varscan2
- LDB3 | c.529del p.A177Pfs*31 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs730880345; ClinVar: uncertain significance; called by mutect2, pindel
- LGALS12 | c.544A>C p.M182L | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV55370411; called by muse, mutect2, varscan2
- LINGO1 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1324374080, COSV62437400; called by muse, mutect2, varscan2
- LINGO3 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV101347278; called by muse, mutect2, varscan2
- LLGL2 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs755787767, COSV51355450; called by muse, mutect2, varscan2
- LOXL2 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755780161, COSV66691556; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | catalogued as rs746133895; called by mutect2, varscan2
- LPA | c.3364A>G p.R1122G | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs375026871; called by muse, mutect2, varscan2
- LPIN3 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1350407533, COSV60036483; called by muse, mutect2, varscan2
- LRBA | c.6307G>A p.E2103K | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769501419, COSV58260738; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRCH1 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs267603839, COSV60844279; called by muse, mutect2, varscan2
- LRCH4 | c.495C>T p.D165= | Splice Region (SNP) | VAF 16/44 reads (36%) | catalogued as rs762682145, COSV53823514; called by muse, mutect2, varscan2
- LRRC36 | c.949A>G p.S317G | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1222403858, COSV52079937; called by muse, mutect2, varscan2
- LRRC7 | c.2230G>A p.V744M (on ENST00000651989 / NM_001370785.2; = p.V711M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.009); catalogued as rs1209899583, COSV50465220; called by muse, mutect2, varscan2
- LRRK2 | c.5710G>A p.A1904T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54154596; called by muse, mutect2, varscan2
- LRRN1 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336644190, COSV100076620; called by muse, mutect2
- LTA | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs1169549387, COSV69304724; called by muse, mutect2, varscan2
- LYPD3 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54988491; called by muse, mutect2, varscan2
- LYPD6B | c.226C>T p.R76* (on ENST00000409029 / NM_001317004.1; = p.R100* on NM_177964.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as rs779982399, COSV54518919; called by muse, mutect2, varscan2
- LYVE1 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.154); catalogued as rs749336203, COSV56282712; called by muse, mutect2, varscan2
- MACF1 | c.13298C>T p.T4433M (on ENST00000372915; = p.T2366M on NM_012090.5) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as rs139081523, COSV57120890, COSV57122820; called by muse, mutect2, varscan2
- MAD1L1 | c.1912G>A p.G638S | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746065050, COSV56235304; called by muse, mutect2, varscan2
- MAGI1 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250552603, COSV58322054, COSV58327645; called by muse, mutect2, varscan2
- MAN2A1 | c.1404del p.F468Lfs*22 | Frame Shift Del (DEL) | VAF 28/66 reads (42%) | catalogued as rs766462976; called by mutect2, varscan2
- MAP3K11 | c.2471dup p.Q826Pfs*36 | Frame Shift Ins (INS) | VAF 18/59 reads (31%) | catalogued as COSV100442225; called by mutect2, pindel, varscan2
- MAP3K13 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV53989421; called by muse, mutect2, varscan2
- MAP3K5 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as rs770548145, COSV62889312; called by muse, mutect2, varscan2
- MAP7 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs372519059, COSV63416761; called by muse, mutect2, varscan2
- MAST1 | c.489C>T p.S163= | Splice Region (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99263752; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 12/25 reads (48%) | catalogued as rs762648935; called by mutect2, pindel, varscan2
- MDGA2 | c.1961C>T p.T654M (on ENST00000399232 / NM_001113498.2; = p.T356M on NM_182830.4) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs758142772, COSV62081973; called by muse, mutect2, varscan2
- MDM2 | c.961del p.L321Ffs*52 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs746910913; called by mutect2, pindel, varscan2
- MDN1 | c.7519A>G p.T2507A | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV65522226; called by muse, mutect2, varscan2
- MED12 | c.6306_6308dup p.Q2115dup | In Frame Ins (INS) | VAF 32/54 reads (59%) | catalogued as rs766775649; called by mutect2, varscan2
- MFAP3L | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as rs759421553, COSV64372253; called by muse, mutect2, varscan2
- MFSD11 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV60624150; called by muse, mutect2, varscan2
- MGAM | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778528944, COSV72073567; called by muse, mutect2, varscan2
- MGAT1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | PolyPhen benign (0.006); catalogued as rs778419570, COSV57134145; called by muse, mutect2, varscan2
- MGLL | c.406C>T p.P136S (on ENST00000398104 / NM_001003794.2; = p.P146S on NM_007283.6) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV54022858; called by muse, mutect2, varscan2
- MIA3 | c.2812C>T p.R938W | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553282645, COSV60513219; called by muse, mutect2, varscan2
- MIB2 | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1216356615, COSV61542719; called by muse, mutect2, varscan2
- MINPP1 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1485394819, COSV64354420; called by muse, mutect2, varscan2
- MIPEP | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751340807, COSV66300716; called by muse, mutect2, varscan2
- MKI67 | c.6691A>G p.T2231A | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV64074608; called by muse, mutect2, varscan2
- MMD2 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV68660715; called by muse, mutect2, varscan2
- MMP19 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs749262995, COSV59451507; called by muse, mutect2, varscan2
- MNAT1 | c.539A>C p.K180T | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54190880; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | catalogued as rs755830405; called by mutect2, varscan2
- MOCS1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs368776652; called by muse, mutect2, varscan2
- MON1B | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.828); catalogued as rs755287354, COSV50247286; called by muse, mutect2, varscan2
- MORN1 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs376122564; called by muse, mutect2, varscan2
- MPIG6B | c.670C>T p.R224W (on ENST00000649779 / NM_138272.3; = p.P230L on NM_025260.4) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs778527258, COSV65389711; called by muse, mutect2, varscan2
- MPP6 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1290964278, COSV99757858, COSV99757912; called by muse, mutect2, varscan2
- MPV17L2 | c.493dup p.Q165Pfs*175 | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | catalogued as rs746591385; called by mutect2, varscan2
- MRGPRX4 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.09); catalogued as rs1343924266, COSV58590607; called by muse, mutect2, varscan2
- MTA3 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV65922071; called by muse, mutect2, varscan2
- MTHFD2L | c.424G>A p.G142S (on ENST00000395759 / NM_001144978.2; = p.G84S on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1223839197, COSV57466659; called by muse, mutect2, varscan2
- MTTP | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs568076672, COSV55506028; called by muse, mutect2, varscan2
- MUC21 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs780528569, COSV66220927; called by muse, mutect2, varscan2
- MUC5B | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.358); catalogued as rs1448515931, COSV71592139; called by muse, mutect2, varscan2
- MYH13 | c.4188del p.K1396Nfs*37 | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | catalogued as rs760402984; called by mutect2, varscan2
- MYH15 | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 46/123 reads (37%) | catalogued as COSV56310899; called by muse, mutect2, varscan2
- MYH7 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as rs1327007939, COSV62517775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.3860C>T p.A1287V | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs1268282594, COSV67965735; called by muse, mutect2, varscan2
- MYH9 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs1472348578, CM147347, COSV53386704; called by muse, mutect2, varscan2
- MYH9 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202023656, COSV53393696; called by muse, mutect2, varscan2
- MYO10 | c.3128C>T p.T1043I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV57022202; called by muse, mutect2, varscan2
- MYO15A | c.8993C>T p.A2998V | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV52757550; called by muse, mutect2, varscan2
- MYO1A | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758088084, COSV55653385; called by muse, mutect2, varscan2
- MYO1E | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 90/107 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752138428, COSV55688007; called by muse, mutect2, varscan2
- NAGLU | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1489785243, COSV56794899; called by muse, mutect2, varscan2
- NBAS | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1283789987, COSV55722635; called by muse, mutect2, varscan2
- NCAPD2 | c.2508del p.F837Sfs*36 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as rs772347389; called by pindel, varscan2
- NCOA5 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 47/107 reads (44%) | catalogued as COSV99275331; called by muse, mutect2, varscan2
- NCOR2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs200569241, COSV62298473; called by muse, mutect2, varscan2
- NCR2 | c.645G>T p.W215C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.79); catalogued as rs990764477, COSV100897261; called by muse, mutect2, varscan2
- NDOR1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs775965430, COSV61287921; called by muse, mutect2, varscan2
- NDUFAF5 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65247013; called by muse, mutect2, varscan2
- NEB | c.3235G>T p.A1079S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV51420115; called by muse, mutect2, varscan2
- NEDD1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV57143630; called by muse, mutect2, varscan2
- NEK5 | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs759481638, COSV62880033; called by muse, mutect2, varscan2
- NEO1 | c.4132G>A p.A1378T | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV56071563; called by muse, mutect2, varscan2
- NEU1 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs772426069, COSV57667351; called by muse, mutect2, varscan2
- NFATC3 | c.3092T>C p.I1031T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV60473997; called by muse, mutect2, varscan2
- NFKBIA | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53752609; called by muse, mutect2, varscan2
- NGEF | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1328624341, COSV50918046; called by muse, mutect2, varscan2
- NIBAN1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.938); catalogued as rs562448693, COSV62284129; called by muse, mutect2, varscan2
- NIP7 | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV54742443; called by muse, mutect2, varscan2
- NIPAL1 | c.198_199del p.Y66* | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | catalogued as rs1401949522; called by mutect2, pindel, varscan2
- NKTR | c.2297del p.N766Ifs*30 | Frame Shift Del (DEL) | VAF 34/82 reads (41%) | catalogued as rs767007251; called by mutect2, varscan2
- NKX2-8 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV51873818; called by muse, mutect2, varscan2
- NKX6-2 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as COSV63973682; called by muse, mutect2, varscan2
- NLE1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.761); catalogued as rs372790802; called by muse, mutect2, varscan2
- NLRC3 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.123); catalogued as rs202116008, COSV57091164; called by muse, mutect2, varscan2
- NLRC5 | c.3027C>T p.L1009= | Splice Region (SNP) | VAF 27/55 reads (49%) | catalogued as rs1379843387, COSV52655823, COSV99348108; called by muse, mutect2, varscan2
- NLRP11 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs115243845; called by muse, mutect2, varscan2
- NPAS4 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100215286; called by muse, mutect2
- NPIPB15 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.337); catalogued as rs759133354, COSV101466049; called by muse, mutect2, varscan2
- NR1I3 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV63468062; called by muse, mutect2, varscan2
- NR2C2 | c.322G>A p.V108I (on ENST00000393102; = p.V127I on NM_003298.5) | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs762221262, COSV60146632; called by muse, mutect2, varscan2
- NR2E1 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64562022; called by muse, mutect2, varscan2
- NR5A1 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as rs981580861, COSV65294564; called by muse, mutect2, varscan2
- NRDE2 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100583666; called by muse, mutect2
- NRXN1 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs773464948, COSV58455452; called by muse, mutect2, varscan2
- NRXN1 | c.2066G>A p.G689D | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58455502; called by muse, mutect2, varscan2
- NSUN7 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV57274011; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP188 | c.4583C>T p.A1528V | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as rs778357869, COSV65330986; called by muse, mutect2, varscan2
- NUP62 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs769926725, COSV100352385; called by muse, mutect2, varscan2
- OAS2 | c.659T>G p.L220R | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV60802627; called by muse, mutect2, varscan2
- OBSCN | c.11687T>A p.L3896Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52778199; called by muse, mutect2, varscan2
- OBSCN | c.22913G>A p.S7638N | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62431519; called by muse, mutect2, varscan2
- OLIG3 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV62988632; called by muse, mutect2, varscan2
- OPRL1 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376128527; called by muse, mutect2, varscan2
- OR10Q1 | c.565del p.V189Sfs*19 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as COSV57470591, COSV57471186, COSV99079566; called by mutect2, pindel, varscan2
- OR2M4 | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV60708342; called by muse, mutect2, varscan2
- OR51A2 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 123/355 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs372608868; called by muse, mutect2, varscan2
- OR5J2 | c.826A>G p.M276V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56621400; called by muse, mutect2, varscan2
- OR5M1 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs781179231, COSV73202106; called by muse, mutect2, varscan2
- OR6B2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as rs761386136, COSV53152501; called by muse, mutect2, varscan2
- OR6C2 | c.632G>A p.C211Y | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV59515490, COSV59516131; called by muse, mutect2, varscan2
- OR6F1 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs1330426417, COSV57467943; called by muse, mutect2, varscan2
- OR9K2 | c.319A>G p.M107V (on ENST00000305377; = p.M85V on NM_001005243.1) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV59532101; called by muse, mutect2, varscan2
- OSBPL1A | c.1433A>C p.D478A | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV60198597; called by muse, mutect2, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as rs780916980; called by mutect2, varscan2
- OSBPL6 | c.2689T>A p.F897I | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51918858; called by muse, mutect2, varscan2
- OSBPL7 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs755578044, COSV50109039; called by muse, mutect2, varscan2
- OSBPL9 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs776013856, COSV61870264; called by muse, mutect2, varscan2
- OTP | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.379); catalogued as rs374616762, COSV100119913; called by muse, mutect2, varscan2
- OXR1 | c.1818C>A p.F606L (on ENST00000442977 / NM_001198532.1; = p.F605L on NM_018002.3) | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100367767; called by muse, mutect2, varscan2
- P2RY8 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs765555908, COSV67177238; called by muse, mutect2
- PABPC3 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV55796483; called by muse, mutect2, varscan2
- PADI3 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as COSV64934598; called by muse, mutect2, varscan2
- PAICS | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 101/269 reads (38%) | PolyPhen benign (0.015); catalogued as COSV51708778; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1085A>G p.E362G (on ENST00000374531 / NM_001037293.2; = p.E394G on NM_053016.6) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs776820674, COSV100093728; called by muse, mutect2, varscan2
- PANX2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.467); catalogued as COSV50292364; called by muse, mutect2, varscan2
- PAQR6 | c.586G>A p.D196N (on ENST00000292291 / NM_001272108.2; = p.D90N on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV52745369; called by muse, mutect2, varscan2
- PCARE | c.3079C>T p.Q1027* | Nonsense Mutation (SNP) | VAF 47/107 reads (44%) | catalogued as COSV59055124; called by muse, mutect2, varscan2
- PCDHA8 | c.2252C>T p.S751L | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1380003956, COSV65326986, COSV65332428; called by muse, mutect2, varscan2
- PCDHB8 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1369164824, COSV99177451; called by muse, mutect2, varscan2
- PCDHB9 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs782288230; called by muse, mutect2, varscan2
- PCDHGA1 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV65296709; called by muse, mutect2, varscan2
- PCDHGB1 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs867459693, COSV53940130; called by muse, mutect2, varscan2
- PCNX3 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs754949156, COSV58419045; called by muse, mutect2, varscan2
- PCNX3 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs751009343, COSV100856668; called by mutect2, varscan2
- PCSK5 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs765807770, COSV65084154; called by muse, mutect2, varscan2
- PDIA3 | c.1024T>C p.F342L | Missense Mutation (SNP) | VAF 108/139 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55856184; called by muse, mutect2, varscan2
- PEX1 | c.2360T>C p.L787P | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99952412; called by muse, mutect2, varscan2
- PGBD5 | c.1237G>A p.A413T (on ENST00000525115; = p.A482T on NM_001258311.2) | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1558189114, COSV58411879; called by muse, mutect2, varscan2
- PGM2 | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV67938827; called by muse, mutect2, varscan2
- PHC3 | c.1345del p.Q449Sfs*2 (on ENST00000494943 / NM_001308116.2; = p.Q461Sfs*2 on NM_024947.4) | Frame Shift Del (DEL) | VAF 28/90 reads (31%) | catalogued as COSV71948757; called by mutect2, pindel, varscan2
- PHKG1 | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs375841179; called by muse, mutect2, varscan2
- PHLDB3 | c.1554G>T p.W518C | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV52669702; called by muse, mutect2, varscan2
- PHLPP1 | c.4513G>A p.E1505K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as rs1200962447, COSV53029411; called by muse, mutect2, varscan2
- PHRF1 | c.1441G>A p.V481M (on ENST00000264555 / NM_001286581.2; = p.V480M on NM_020901.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs372144693, COSV99212734; called by muse, mutect2, varscan2
- PI4K2A | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754584429, COSV65701478; called by muse, mutect2, varscan2
- PIK3CG | c.3154C>T p.R1052W | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs765204428, COSV63248807; called by muse, mutect2, varscan2
- PIN4 | c.309_310insT p.G104Wfs*3 (on ENST00000664196; = p.G79Wfs*3 on NM_006223.4) | Frame Shift Ins (INS) | VAF 11/108 reads (10%) | catalogued as COSV54485001; called by mutect2, pindel, varscan2
- PIP5K1C | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58950828; called by muse, mutect2, varscan2
- PKD1 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.04); catalogued as rs774050983, COSV51916966; called by muse, mutect2, varscan2
- PKMYT1 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.273); catalogued as COSV51891554; called by muse, mutect2, varscan2
- PKN2 | c.1550G>T p.W517L | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60131746; called by muse, mutect2, varscan2
- PLCB4 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs751597030, COSV53802981; called by muse, mutect2, varscan2
- PLCG1 | c.3565G>A p.A1189T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV54819055; called by muse, mutect2, varscan2
- PLEC | c.9439G>A p.V3147I (on ENST00000322810 / NM_201380.4; = p.V3037I on NM_000445.5) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs782145186, COSV59640138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEK | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs200352669, COSV52250616, COSV52252675; called by muse, mutect2, varscan2
- PLEKHA7 | c.2858T>G p.V953G | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60580537; called by muse, mutect2, varscan2
- PLEKHM3 | c.28A>C p.S10R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66816708; called by muse, mutect2, varscan2
- PNPLA2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs145699347; called by muse, mutect2, varscan2
- PNPLA8 | c.1258C>T p.L420F | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57551389, COSV57552596; called by muse, mutect2, varscan2
- POLR2B | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV100108370; called by muse, mutect2, varscan2
- POMGNT2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769075803, COSV60953559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POU3F1 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65948875; called by muse, mutect2, varscan2
- PPARD | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs772150465, COSV61098596, COSV61099795; called by muse, mutect2, varscan2
- PPFIA2 | c.3397G>A p.G1133S | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470742734, COSV61033523; called by muse, mutect2, varscan2
- PPFIA2 | c.2549G>A p.R850Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as COSV61033538; called by muse, mutect2, varscan2
- PPFIA3 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348327728, COSV61951942; called by muse, mutect2, varscan2
- PPFIA4 | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV99830563; called by muse, mutect2, varscan2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 26/56 reads (46%) | catalogued as rs753902804; called by mutect2, varscan2
- PPP2R2B | c.367C>T p.R123C (on ENST00000394409; = p.R189C on NM_181674.2) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1373691645, COSV60765529; called by muse, mutect2, varscan2
- PPP2R2C | c.1052+2T>C p.X351_splice | Splice Site (SNP) | VAF 25/56 reads (45%) | catalogued as COSV59444508; called by muse, mutect2, varscan2
- PRAM1 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs546942995, COSV55313905; called by muse, mutect2, varscan2
- PRAM1 | c.560C>A p.A187E | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV55313917; called by muse, mutect2, varscan2
- PRDM16 | c.1852A>G p.T618A | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV54591480; called by muse, mutect2, varscan2
- PRDM16 | c.2956C>T p.R986C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV54580808; called by muse, mutect2, varscan2
- PREX2 | c.2804C>A p.P935H | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55772250; called by muse, varscan2
- PROCR | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1277077407, COSV53825901; called by muse, mutect2, varscan2
- PROKR2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54086843; called by muse, mutect2
- PROM1 | c.1408A>T p.T470S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV71699479; called by muse, mutect2, varscan2
- PROS1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs769125007, COSV67776459; called by muse, varscan2
- PROSER1 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 22/119 reads (18%) | catalogued as COSV61487550, COSV61488822; called by muse, varscan2
- PROX1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs112763420; called by muse, mutect2, varscan2
- PRPF38A | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs1322447419, COSV57122494, COSV57123001; called by muse, mutect2, varscan2
- PRR12 | c.871G>A p.A291T (on ENST00000615927; = p.A1112T on NM_020719.3) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1415283759, COSV101330805; called by muse, mutect2, varscan2
- PRRC2B | c.4364G>A p.R1455H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as rs1483140843, COSV100621364, COSV61934761; called by muse, mutect2, varscan2
- PRSS27 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs770792515, COSV57013450; called by muse, mutect2, varscan2
- PRTN3 | c.497del p.P166Qfs*42 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs1195204654; called by mutect2, varscan2
- PSG2 | c.217A>G p.R73G | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV68884700; called by muse, mutect2, varscan2
- PSPC1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58888299; called by muse, mutect2, varscan2
- PSPH | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs201419960; called by mutect2, varscan2
- PTGER3 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60692191; called by muse, mutect2, varscan2
- PTGS1 | c.381del p.T128Pfs*17 | Frame Shift Del (DEL) | VAF 36/154 reads (23%) | catalogued as rs779702921; called by mutect2, pindel, varscan2
- PTK2B | c.1991A>G p.Y664C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV57751893; called by muse, mutect2, varscan2
- PTPMT1 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs201520358; called by muse, mutect2, varscan2
- PTPRB | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.311); catalogued as COSV57701949; called by muse, mutect2, varscan2
- PTPRJ | c.2426G>A p.C809Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV69252387; called by muse, mutect2, varscan2
- PTPRS | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1447785084, COSV53620614; called by muse, mutect2, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel
- PYGB | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868361956, COSV99405062, COSV99405190; called by muse, mutect2, varscan2
- RAB11FIP4 | c.232dup p.V78Gfs*46 | Frame Shift Ins (INS) | VAF 24/60 reads (40%) | catalogued as rs751772020; called by mutect2, pindel, varscan2
- RAB11FIP5 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs202050559; called by muse, mutect2, varscan2
- RAB3IP | c.790C>A p.P264T (on ENST00000550536 / NM_175623.4; = p.P248T on NM_022456.5) | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56083758, COSV56086794; called by muse, mutect2, varscan2
- RABAC1 | c.281del p.P94Lfs*33 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as COSV99706064; called by mutect2, pindel, varscan2
- RABL6 | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as rs1292284225, COSV61035862; called by muse, mutect2, varscan2
- RAD18 | c.310_312del p.P104del | In Frame Del (DEL) | VAF 25/85 reads (29%) | catalogued as rs766404991; called by mutect2, pindel, varscan2
- RADX | c.1798C>T p.R600W | Missense Mutation (SNP) | VAF 101/131 reads (77%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1457081415, COSV65318115; called by muse, mutect2, varscan2
- RALGAPA1 | c.2587G>T p.G863C | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV51884012; called by muse, mutect2, varscan2
- RAN | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV54562626; called by muse, mutect2, varscan2
- RANGAP1 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs143560227; called by muse, mutect2, varscan2
- RAPGEF3 | c.1121G>A p.G374D (on ENST00000389212; = p.G332D on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV50208326; called by muse, mutect2, varscan2
- RASL11A | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV99611178; called by muse, mutect2, varscan2
- RASSF1 | c.667C>T p.R223C (on ENST00000357043 / NM_170714.2; = p.R219C on NM_007182.5) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs376674291; called by muse, mutect2, varscan2
- RASSF4 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs377064821; called by muse, mutect2, varscan2
- RAVER2 | c.1685C>T p.A562V (on ENST00000294428 / NM_001366165.1; = p.A549V on NM_018211.4) | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV53807591; called by muse, mutect2, varscan2
- RBM15B | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs372043035, COSV60043111; called by muse, mutect2, varscan2
- RBM33 | c.3089del p.G1030Afs*52 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as COSV62031451; called by mutect2, varscan2
- RBM33 | c.3265C>T p.R1089W | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62031637; called by muse, mutect2, varscan2
- RFC2 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs1316344856, COSV99278130; called by muse, mutect2
- RFX2 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs200963067, COSV57941756; called by muse, mutect2, varscan2
- RGL2 | c.608del p.G203Afs*49 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs762949421; called by mutect2, varscan2
- RHPN1 | c.1327A>G p.T443A | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56647026; called by muse, mutect2, varscan2
- RIOX1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs370721077; called by muse, mutect2, varscan2
- RNF166 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as rs377640480; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs755128667, COSV68457540; called by pindel, varscan2
- RNF43 | c.832_834del p.E278del | In Frame Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs1174509032; called by pindel, varscan2
- RPL39L | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV56219900; called by muse, mutect2, varscan2
- RPS7 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs200400906, COSV59232964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTF1 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.127); catalogued as rs766020815, COSV67478137; called by muse, mutect2, varscan2
- RTKN | c.1384G>A p.A462T (on ENST00000272430 / NM_001015055.2; = p.A449T on NM_033046.2) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs765799493, COSV51963514; called by muse, mutect2, varscan2
- RYR1 | c.7207C>T p.R2403C | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs1241302558, COSV62098375, COSV62106255; called by mutect2, varscan2
- RYR2 | c.3026G>A p.R1009Q | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs754812132, COSV63687404, COSV63691183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs745955551, COSV101214731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.5271G>T p.E1757D | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV66790938; called by muse, mutect2, varscan2
- S100A14 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV59884663; called by muse, mutect2, varscan2
- SAMD14 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.133); catalogued as COSV50303767; called by muse, mutect2, varscan2
- SAMD7 | c.1253C>A p.P418H | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.037); catalogued as COSV59418984; called by muse, mutect2, varscan2
- SBNO1 | c.3607G>A p.D1203N (on ENST00000420886; = p.D1202N on NM_018183.5) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as rs1566025579, COSV57341933; called by muse, mutect2, varscan2
- SCG2 | c.464A>C p.Q155P | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.629); catalogued as rs777727782, COSV59540273; called by muse, mutect2, varscan2
- SCN3A | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs755792980, COSV51810871; called by muse, mutect2, varscan2
- SCN8A | c.5882C>T p.A1961V | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as COSV61982342; called by muse, mutect2, varscan2
- SCP2 | c.382A>G p.S128G | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV101027254; called by muse, mutect2, varscan2
- SCRIB | c.3943G>A p.A1315T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs782736261, CM137640, COSV57587458; called by muse, mutect2, varscan2
- SDK1 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs770272131, COSV67363992; called by muse, mutect2, varscan2
- SEC61G | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV61856028; called by muse, mutect2, varscan2
- SELENOM | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs1262942038, COSV100294060; called by muse, mutect2, varscan2
- SEPTIN4 | c.1284G>T p.W428C | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58727978; called by muse, mutect2, varscan2
- SERPINA1 | c.458A>C p.K153T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as COSV100872199; called by muse, mutect2, varscan2
- SESTD1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs144405691; called by muse, mutect2, varscan2
- SF3A2 | c.610A>G p.K204E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV99678108; called by muse, mutect2, varscan2
- SF3B3 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56787838; called by muse, mutect2, varscan2
- SFMBT2 | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs759241379, COSV62810024, COSV62817066; called by muse, mutect2, varscan2
- SFMBT2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868013820, COSV62808092; called by muse, varscan2
- SGSM3 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.025); catalogued as rs750651736, COSV50652490; called by muse, mutect2, varscan2
- SH3BP2 | c.800G>A p.C267Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV62554256; called by muse, mutect2, varscan2
- SHANK1 | c.1906G>A p.V636M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775059699, COSV53251517; called by muse, mutect2, varscan2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs746556543; called by mutect2, varscan2
- SHISA5 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs140407949; called by muse, mutect2, varscan2
- SIK3 | c.2033A>G p.K678R (on ENST00000445177 / NM_001366686.2; = p.K636R on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.635); catalogued as COSV52614885; called by muse, mutect2, varscan2
- SIPA1L3 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs141710131; called by mutect2, varscan2
- SIX3 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53227084; called by muse, mutect2
- SKAP1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV61146940; called by muse, mutect2, varscan2
- SLC13A2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs146998121, COSV58993822; called by muse, mutect2, varscan2
- SLC13A4 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100818976; called by mutect2, varscan2
- SLC16A8 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV57635504; called by muse, mutect2, varscan2
- SLC22A10 | c.220A>G p.R74G | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1173861728, COSV60421426; called by muse, mutect2, varscan2
- SLC25A11 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs370162748; called by muse, mutect2, varscan2
- SLC25A2 | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53403947; called by muse, mutect2, varscan2
- SLC26A3 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758633508, COSV60639959; called by muse, mutect2, varscan2
- SLC27A5 | c.575T>G p.L192R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99564646; called by muse, mutect2, varscan2
- SLC2A11 | c.1013G>A p.R338H (on ENST00000345044 / NM_001024938.4; = p.R345H on NM_030807.5) | Missense Mutation (SNP) | VAF 145/348 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs372590867; called by muse, mutect2, varscan2
- SLC2A13 | c.1440G>T p.W480C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV55118175; called by muse, mutect2
- SLC2A2 | c.557del p.G186Efs*65 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as rs771799491; called by mutect2, pindel, varscan2
- SLC2A6 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782337904, COSV99390470; called by muse, mutect2, varscan2
- SLC36A1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.409); catalogued as rs758625230, COSV54651946; called by muse, mutect2, varscan2
- SLC39A10 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.322); catalogued as rs1197686246, COSV62767569; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC4A3 | c.2357A>T p.D786V | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV56094150; called by muse, mutect2, varscan2
- SLC5A9 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 45/111 reads (41%) | catalogued as rs771100263, COSV52583738; called by muse, mutect2, varscan2
- SLC6A1 | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV55115652; called by muse, mutect2, varscan2
- SLC6A12 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768166004, COSV62883760; called by muse, mutect2, varscan2
- SLCO1B1 | c.977del p.F326Sfs*19 | Frame Shift Del (DEL) | VAF 35/120 reads (29%) | catalogued as rs763545439; called by mutect2, pindel, varscan2
- SLFN5 | c.2093del p.P698Lfs*21 | Frame Shift Del (DEL) | VAF 42/120 reads (35%) | catalogued as rs745817019; called by mutect2, pindel, varscan2
- SLITRK5 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.119); catalogued as rs1364096101, COSV61523126; called by muse, mutect2, varscan2
- SLX4 | c.3902G>A p.G1301E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1307466531, COSV53564335; called by muse, varscan2
- SMARCA4 | c.4051G>A p.D1351N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs1318154109, COSV60795432; called by muse, mutect2, varscan2
- SMARCC2 | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV53238876; called by muse, mutect2, varscan2
- SMPD4 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as rs757934173, COSV60080474; called by muse, mutect2, varscan2
- SNRK | c.1700G>T p.R567L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56068217; called by muse, mutect2, varscan2
- SNW1 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV55054562; called by muse, mutect2, varscan2
- SNX13 | c.1043T>C p.I348T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV68065239; called by muse, mutect2, varscan2
- SOCS3 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as COSV58270448; called by muse, mutect2, varscan2
- SOCS6 | c.1304A>G p.H435R | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV67546452; called by muse, mutect2, varscan2
- SORCS1 | c.3263C>T p.A1088V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.241); catalogued as rs758327035, COSV53868999; called by muse, mutect2, varscan2
- SOS2 | c.3787C>T p.P1263S | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV53566572, COSV99365599; called by muse, mutect2, varscan2
- SOX17 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs1274955948, COSV52026876; called by muse, mutect2
- SPARCL1 | c.743A>G p.D248G | Missense Mutation (SNP) | VAF 92/228 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV56803845; called by muse, mutect2, varscan2
- SPEF2 | c.4591G>A p.E1531K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs201259522, COSV57429353; called by muse, mutect2, varscan2
- SPEG | c.6697del p.Q2233Rfs*6 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs752907815; called by mutect2, varscan2
- SPOCK1 | c.735C>A p.C245* | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | catalogued as COSV56450343; called by muse, mutect2, varscan2
- SPON2 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99335356; called by muse, mutect2, varscan2
- SPTB | c.5956C>T p.Q1986* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV67632121; called by muse, mutect2, varscan2
- SPTBN2 | c.6136G>A p.D2046N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1042146441, COSV59452728; called by muse, mutect2, varscan2
- SPTLC2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53640247; called by muse, mutect2, varscan2
- SRCAP | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796432, COSV52672771; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRCAP | c.5633dup p.P1879Tfs*21 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | catalogued as rs748467821; called by mutect2, varscan2
- SRGAP1 | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV61898449; called by muse, mutect2, varscan2
- SRGAP3 | c.107A>C p.E36A | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64533661; called by muse, mutect2, varscan2
- SRP68 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57162799; called by muse, mutect2, varscan2
- SRPK2 | c.1625C>T p.T542M | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480685542, COSV61961237; called by muse, mutect2, varscan2
- SRSF1 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99365351; called by muse, mutect2, varscan2
- SSRP1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs1031692895, COSV53479569; called by muse, mutect2, varscan2
- STAB2 | c.5540G>A p.G1847D | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV66339549; called by muse, mutect2, varscan2
- STAC | c.1116C>A p.C372* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV56211284; called by muse, mutect2, varscan2
- STAG1 | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs774492433, COSV52610653; called by muse, mutect2, varscan2
- STAT1 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs753414973, COSV100738888; called by muse, varscan2
- STK3 | c.519T>C p.D173= | Splice Region (SNP) | VAF 11/35 reads (31%) | catalogued as rs748985361, COSV69223713; called by muse, mutect2, varscan2
- STMN3 | c.8G>T p.S3I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as COSV58894801; called by muse, varscan2
- STOML3 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as rs575718463, COSV101105416; called by muse, mutect2, varscan2
- STON2 | c.1509G>T p.W503C (on ENST00000649389 / NM_001366849.2; = p.W446C on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50845299; called by muse, mutect2, varscan2
- STRN4 | c.1864G>A p.V622I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV54418654; called by muse, mutect2, varscan2
- SUN1 | c.1813G>A p.V605M (on ENST00000405266 / NM_001367651.1; = p.V485M on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as rs537139636, COSV67449649; called by muse, mutect2, varscan2
- SUPT16H | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs201996123; called by muse, mutect2, varscan2
- SUPT6H | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.905); catalogued as rs897919382, COSV58924533; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SWAP70 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756309764, COSV59664082; called by muse, mutect2, varscan2
- SYCP1 | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.649); catalogued as rs771129520, COSV65695325; called by muse, mutect2, varscan2
- SYNDIG1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762805806, COSV65235257; called by muse, mutect2, varscan2
- SYNGAP1 | c.3409-1G>A p.X1137_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as COSV53381614; called by muse, mutect2, varscan2
- SYNPO | c.2066C>A p.A689E (on ENST00000394243 / NM_001166208.2; = p.A445E on NM_007286.6) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV100302451; called by muse, mutect2, varscan2
- SYT16 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1257839456, COSV70856904; called by muse, mutect2, varscan2
- TACR1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59482013; called by muse, mutect2, varscan2
- TAF1L | c.2605G>A p.A869T | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1192791006, COSV54259748, COSV54263571; called by muse, mutect2, varscan2
- TAF3 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201464808, COSV100720108; called by muse, mutect2, varscan2
- TASP1 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV61813176; called by muse, mutect2, varscan2
- TATDN2 | c.2228C>A p.P743Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV55052102; called by muse, mutect2, varscan2
- TBC1D10B | c.2178G>T p.K726N | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.527); catalogued as rs571905839, COSV59768842; called by muse, mutect2, varscan2
- TBCEL | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1317317232, COSV52460009; called by muse, mutect2, varscan2
- TBL1Y | c.1447-2A>G p.X483_splice | Splice Site (SNP) | VAF 40/52 reads (77%) | catalogued as COSV100667266, COSV60733148; called by muse, mutect2, varscan2
- TBRG4 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs755237535, COSV51831728, COSV51834669; called by muse, mutect2, varscan2
- TBX10 | c.666G>T p.E222D | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV56875684; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
570 further variants in this file (252 protein-altering or splice-affecting, 290 silent, 28 other) are not listed here.
